Surgical pathology report (de-identified scan), TCGA case TCGA-KM-8476, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-8476-01A (Primary Tumor).

[page 1 of 2]
MEDICAL RECORD**Surgical Pathology Report****Surgical Pathology Report****PATIENT:**
ACCOUNT#:**DOB:****AGE:****SEX:****ATTENDING:****REQUESTING:****CONTACT NO:** (MD) -**COPIES TO:****MRN:****RECEIVED DATE:****PROCEDURE DATE:****SIGN-OUT DATE:****LOCATION:****ROOM:****DIAGNOSIS:**

Kidney, right (nephrectomy): Renal cell carcinoma, chromophobe type. The tumor does not penetrate the renal capsule. Vascular and ureteral margins are free of tumor.

Adrenal gland; no tumor seen.

CLINICAL INFORMATION: HISTORY: INCIDENTAL RIGHT KIDNEY MASS EXAM IS RELATED TO ORDERING PROTOCOL

PROCEDURE: PREOP DX: #RIGHT KIDNEY TUMOR POSTOP DX: SAME OPERATIVE FINDINGS: RIGHT KIDNEY WITH MASS

SPECIMENS SUBMITTED: KIDNEY, RIGHT

GROSS DESCRIPTION:

The specimen is received fresh in a container labeled "right kidney". It consists of a 495 gram kidney, with an attached adrenal gland. The tumor is processed for procurement provided by UOB. The kidney is opened prior to arrival to the Surgical Pathology suite to reveal a brown-tan tumor, measuring 7 cm. in maximum diameter, abutting the renal capsule and located in the superior pole. The perinephric fat around the tumor is inked black avoiding inking the cut tumor. The specimen is serially sectioned and representative sections of the tumor are submitted for permanent. The adrenal gland is also received sectioned prior to arrival in Surgical Pathology. Two pieces were procured by UOB. The adrenal gland is 6.5 x 2.5 x 0.5 cm. The adrenal gland is serially sectioned to reveal an orange cut surface without gross lesions. Representative sections are submitted for permanent.

Patient Identification

Surgical Pathology Report

[page 2 of 2]
MEDICAL RECORD**Surgical Pathology Report**

The ureteral and vascular margins are identified and are grossly unremarkable and patent. White cassettes submitted:

- A - ureteral and vascular margins
- B - adrenal
- C through E - tumor, perinephric fat
- F and G - tumor, kidney parenchyma
- H and I - tumor, pelvis
- J and K - tumor, periphery
- L - tumor, pelvis
- M and N - kidney
- O - possible hilar lymph nodes

Patient Identification

Surgical Pathology Report

Source: NCI Genomic Data Commons file 7809efea-619f-4c30-a966-cb75f2aa9c06 (TCGA-KM-8476.4721AB86-F4FA-43D9-A4AE-0BE5814335DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).